CCDI case PBBXJB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4f406507-2b71-48c4-a981-4b988409bc94

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9401/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,386 days).

Biospecimens (3 samples)
- Sample 0DK3E8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK3EC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK3EP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
